Somatic mutation profile of tumor specimen 0DCJR8 from CCDI case PBBMII, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 10.8 years (3,959 days).
Specimen 0DCJR8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0838a63f-9814-473d-91fc-dd1538205215.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCJR6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4be0a94a-523d-409d-a6be-ff5714368067

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SDHA | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 286/993 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs139881415; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- INO80D | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 32/988 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV68959693; called by muse, mutect2
- RSKR | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 28/646 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV56384294; called by muse, mutect2
- SLFN11 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 40/857 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); catalogued as COSV57698846; called by muse, mutect2
- TAB2 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 329/950 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as rs937387474; called by muse, mutect2, varscan2
- TIE1 | c.2551G>A p.G851S | Missense Mutation (SNP) | VAF 173/481 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931782166; called by muse, mutect2, varscan2
- BRWD3 | c.2939T>A p.L980H | Missense Mutation (SNP) | VAF 394/1047 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FLOT1 | c.49T>A p.C17S | Missense Mutation (SNP) | VAF 196/468 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- INTS7 | c.2100G>C p.L700F | Missense Mutation (SNP) | VAF 46/1558 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- LACTBL1 | c.459G>C p.K153N (on ENST00000618559; = p.K198N on NM_001289974.2) | Missense Mutation (SNP) | VAF 110/466 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MMP24 | c.1793G>C p.G598A | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.068); called by muse, mutect2
- PCDH9 | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 243/668 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABGGTA | c.1571C>A p.A524E | Missense Mutation (SNP) | VAF 32/647 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- SLFN11 | c.2003A>C p.D668A | Missense Mutation (SNP) | VAF 42/1486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TIGD2 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 357/993 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRA2 | c.1170T>C p.S390= | Silent (SNP) | VAF 523/1437 reads (36%) | catalogued as rs1451059276; called by muse, mutect2, varscan2
- NSMAF | c.924A>G p.G308= | Silent (SNP) | VAF 34/738 reads (5%) | catalogued as rs1409641022; called by muse, mutect2
- PI16 | c.1221C>T p.T407= | Silent (SNP) | VAF 182/510 reads (36%) | catalogued as rs755120849, COSV65320647; called by muse, mutect2, varscan2
- SRBD1 | c.2835G>C p.L945= | Silent (SNP) | VAF 66/1394 reads (5%) | called by muse, mutect2
- STOX2 | c.1557C>T p.D519= | Silent (SNP) | VAF 24/384 reads (6%) | catalogued as rs977195474, COSV100408286, COSV57852651; called by muse, mutect2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 33/964 reads (3%) | called by muse, mutect2
- WRAP53 | c.1164+55G>C | Intron (SNP) | VAF 45/180 reads (25%) | called by muse, mutect2, varscan2
